Somatic mutation profile of tumor specimen TCGA-AB-2913-03A (aliquot TCGA-AB-2913-03A-01W-0732-08) from TCGA case TCGA-AB-2913, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.7 years (22,553 days).
Specimen TCGA-AB-2913-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8214333-68d5-49da-a03f-a7848aca33dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2913-11A (Solid Tissue Normal), aliquot TCGA-AB-2913-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e29bc99-3f20-4e1b-bcdd-599b5f73211b

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137854556, CM000802, CM983421, COSV100648616, COSV62196628, COSV62224419; ClinVar: pathogenic; called by muse, mutect2
- ATP2B2 | c.2666C>T p.T889M (on ENST00000352432; = p.T855M on NM_001683.5) | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1310353379, COSV59505224; called by muse, mutect2, varscan2
- HSD17B1 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV56798493; called by mutect2, varscan2
- RHO | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960679; called by muse, mutect2
- ALPK3 | c.3237G>A p.E1079= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV51932367; called by muse, mutect2, varscan2
- PCDHGA6 | c.2121C>T p.F707= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs185484474, COSV53983416; called by muse, varscan2
